Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7473, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7473-01A (Primary Tumor).

Addendum Discussion:

Scattered MIB-1 reactive cells are present throughout the tumor. A labeling index of 6.1% is seen in the most proliferative areas. This is an intermediate level of proliferation activity. While higher than commonly seen in low grade oligodendrogliomas, it does not warrant classification as anaplastic.

Addendum Diagnosis:

Brain tumor, biopsy and resection:

Low grade oligoastrocytoma (WhoGrade II)

MIB-1 Labeling Index = 6.1%

Microscopic Descriptions:

Sections of gray and white matter demonstrate a diffusely infiltrating glioma. The tumor is mildly to moderately hypercellular. It is composed of cells with round to somewhat irregular nuclei and scant processes. Most have perinuclear halos. Only a rare mitotic figure is seen. No microvascular proliferation or necrosis is present.

Source: NCI Genomic Data Commons file 1e2d485b-d258-40d7-864f-fa5a5c96571d (TCGA-HT-7473.6F87A2EE-CB07-4D62-9F16-F5A47C866B01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).